Somatic mutation profile of tumor specimen MP2PRT-PAPBVD-TMP1-A (aliquot MP2PRT-PAPBVD-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPBVD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (904 days).
Specimen MP2PRT-PAPBVD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45063030-92fc-4c08-aa06-c0521388b23f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBVD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBVD-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe256790-cba1-439d-929c-25c939f92813

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3113G>T p.G1038V | Missense Mutation (SNP) | VAF 138/299 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as CM1512459; called by muse, mutect2, varscan2
- NTM | c.210C>A p.N70K | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STPG2 | c.1107T>C p.H369= | Silent (SNP) | VAF 147/360 reads (41%) | catalogued as COSV99759773; called by muse, mutect2, varscan2
- TLR7 | c.3132G>A p.V1044= | Silent (SNP) | VAF 102/116 reads (88%) | called by muse, mutect2, varscan2
